TARGET case TARGET-15-SJMPAL042940 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d7aeac10-a0d3-471d-aabd-93c6c3ae10d1

Demographics
Sex at birth: male; Age at index: 7 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 7.9 years (2,902 days); Year of diagnosis: 2002.

Follow-up (1 entry)
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 2.9 ×10³/µL.

Biospecimens (2 samples)
- Sample TARGET-15-SJMPAL042940-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-15-SJMPAL042940-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Protocol: Westmead
- WBC at Diagnosis: 2.9
- Initial Therapy: AML
- Karyotype: 46, XY (60%). The remaining cells (40%) were abnormal with pseudo - tetraploidy. Numerical abnormalities affected all chromosomes and in addition, all cells had a structural rearrangement of chromosome 17[add(17p)].
- WHO ALAL Classification: T/M
- WHO Dx: T/M
